Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6294, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6294-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. RIGHT COLON RESECTION
- B. LIVER BX

DIAGNOSIS:

RIGHT COLON, RIGHT HEMICOLECTOMY:

- EXOPHYTIC ULCERATED INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA OF CECUM ARISING IN TUBULOVILLOUS ADENOMA WITH FULL MUSCLE WALL THICKNESS INVASION AND EXTENSION TO SUBSEROUS FAT, METASTASIS TO TWO OUT OF TEN PERICOLIC LYMPH NODES (2/10).
- PROXIMAL AND DISTAL MARGINS OF RESECTION, NEGATIVE FOR TUMOR.
- SIZE OF TUMOR -4 X 3.7 X 3.5 CM.

LIVER, BIOPSY:

- METASTATIC ADENOCARCINOMA CONSISTENT WITH METASTASIS FROM THE ABOVE CECAL ADENOCARCINOMA.

COLORECTAL CANCER TEMPLATE

Tumor Size (cm):	4 x 3.7 x 3.5 cm
Histologic Type:	Adenocarcinoma
Grade/Differentiation:	G2, Moderate
Invasion Depth:	Subserosa
Invasion Vasc/Lymphatic:	no
Invasion Perineural:	Absent
Extension to Adj. Areas:	No
Margins:	Free
Lymph Nodes:	N1, Positive (2/10)
Stage Pathology:	pT3N1
Implants:	Absent
Precursor:	Present - tubulovillous adenoma
Non-neoplastic areas:	

Staging:

Tis: CIS

T1: Submucosa, Intraepithelial or invasion of lamina propria

T2: Into muscularis propria

T3: Thru muscularis propria

T4: Thru peritoneum or to other areas

- Includes invasion of other segments of the colorectum by way of the serosa

Regional Lymph Nodes (N)

N0: No lymph node metastasis

N1: 1-3 Lymph nodes positive

N2: ? 4 Lymph nodes positive

7-14 Lymph nodes should be examined

SPECIMEN(S):

- A. RIGHT COLON RESECTION
- B. LIVER BX

CLINICAL HISTORY:

with ca. colon

GROSS DESCRIPTION:

[page 2 of 2]
RIGHT COLON RESECTION

Specimen consists of resected short segment of right colon measuring 15 cm in length, with attached adherent indurated adipose tissue. Large firm palpable mass occupies mid portion of the specimen, which when the specimen is opened, shows an obstructing circumferential exophytic tumor measuring 4 x 3.7 x 3.5 cm, involving cecum and extending to ileocecal valve and seen 3 cm from ileal margin and 6 cm from distal colonic margin of resection. The tumor on sections shows a tan-cream-white surface and infiltrates entire colonic wall with apparent extension to subjacent adipose tissue. Tumor occludes cecal lumen. Attached adipose tissue measures 11 x 5 x 2.5 cm. Appendix is not identified. Multiple sections submitted and labelled as follows.

A1-A4: one transverse section of tumor divided into four sections

A5-A7: additional tumor representative

A8: colonic margin

A9: representative of colon

A10: representatives of ileum

A11: distal ileal margin

A12: three lymph nodes, one bisected and inked

A13: three lymph nodes, one inked and bisected

A14: three lymph nodes

A15: one bisected lymph node

LIVER BIOPSY

Received in formalin is a portion of tan brown soft tissue measuring 1.2x0.7x0.5cm. which is previously partially bisected. The specimen is further sectioned and submitted completely in cassette B.

Source: NCI Genomic Data Commons file 67435622-6675-4cfb-9ef8-10532de933fd (TCGA-G4-6294.42CC13EA-0257-453D-8CC0-5AF79D8EB6A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).